Somatic mutation profile of tumor specimen C3N-03755-01 (aliquot CPT0248080006) from CPTAC case C3N-03755, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.9 years (25,165 days).
Specimen C3N-03755-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ec6d525-1986-415e-81a0-8d5fb7e641cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03755-31 (Blood Derived Normal), aliquot CPT0248100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/007ddf7f-3d76-4cab-81ef-f98007b97ef6

The open-access MAF lists 75 somatic variants for this specimen: 49 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 19, 3'UTR 3, Intron 2, Frame Shift Del 2, RNA 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 2210/2601 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.987_990del p.N329Kfs*14 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs587782304; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAM32 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.648); catalogued as rs199914358, COSV99060615; called by muse, mutect2, varscan2
- ADRA1B | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.183); catalogued as rs774114012, COSV60704235; called by muse, mutect2, varscan2
- ALOX12B | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757119807; called by muse, mutect2, varscan2
- BASP1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as rs747312829, COSV59473488; called by muse, mutect2, varscan2
- C17orf75 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1257679991; called by muse, mutect2
- C6orf15 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as rs770869294, COSV52537677; called by muse, mutect2, varscan2
- CFAP251 | c.1396A>G p.M466V | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs774686160; called by muse, mutect2, varscan2
- CPED1 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.045); catalogued as rs187097612; called by muse, mutect2, varscan2
- DNAH11 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs200388651; called by muse, mutect2, varscan2
- DNER | c.2207A>G p.D736G | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59178638; called by muse, varscan2
- DSG4 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57397410; called by muse, mutect2, varscan2
- DUOX2 | c.3260C>T p.A1087V | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs776772769, COSV66533103; called by muse, mutect2
- EBF1 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.048); catalogued as rs760492043; called by muse, mutect2, varscan2
- EPB41L4B | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 99/483 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs536573534; called by muse, mutect2, varscan2
- FMNL1 | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767522144; called by muse, mutect2, varscan2
- GSK3B | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1269622391, COSV51770321; called by muse, mutect2, varscan2
- HTR3C | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs143287242; called by muse, mutect2, varscan2
- KRT33A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 110/582 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as rs754832467, COSV50371693; called by muse, mutect2, varscan2
- MMEL1 | c.2044G>A p.G682R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776012302; called by muse, mutect2, varscan2
- MOB1B | c.124C>G p.R42G | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV58673920; called by muse, mutect2
- OOEP | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV64859416; called by muse, mutect2, varscan2
- OR10G4 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as rs772130982, COSV57976989, COSV57977234; called by muse, mutect2, varscan2
- OR10G4 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201358968; called by muse, mutect2, varscan2
- OR2W3 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs201932045, COSV64457575; called by muse, mutect2
- PCDHA5 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 73/412 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1554129666, COSV65350345; called by muse, mutect2, varscan2
- SLC30A3 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 83/440 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs756037276, COSV51984265; called by muse, mutect2, varscan2
- SSTR5 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.191); catalogued as rs371990445; called by muse, mutect2, varscan2
- STAP1 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99609306; called by muse, mutect2, varscan2
- TJP3 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs146857520; called by muse, mutect2, varscan2
- ZNF8 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs761083726; called by muse, mutect2, varscan2
- ABCA6 | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CHD6 | c.2200C>G p.L734V | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTNAP5 | c.3427G>A p.V1143I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DNAH6 | c.11616del p.K3872Nfs*20 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- FOXF2 | c.1328T>G p.V443G | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRT4 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 74/512 reads (14%) | called by muse, mutect2, varscan2
- NPAP1 | c.2531A>G p.K844R | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- PLEKHS1 | c.919G>T p.D307Y (on ENST00000369310 / NM_182601.1; = p.D313Y on NM_024889.5) | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PRG3 | c.561C>G p.Y187* | Nonsense Mutation (SNP) | VAF 39/266 reads (15%) | called by muse, mutect2, varscan2
- RHCE | c.362T>C p.M121T | Missense Mutation (SNP) | VAF 85/522 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RTF2 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SCGB3A2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPGS1 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 11/341 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- TRPC6 | c.296A>G p.E99G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC45B | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- UNC45B | c.1022T>G p.L341R | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- WDR75 | c.764C>G p.A255G | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.499); called by muse, mutect2
- AHNAK2 | c.17058A>G p.E5686= | Silent (SNP) | VAF 48/182 reads (26%) | called by muse, mutect2, varscan2
- BMX | c.921A>G p.E307= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- C4BPA | c.579C>T p.Y193= | Silent (SNP) | VAF 57/224 reads (25%) | catalogued as rs200253338; called by muse, mutect2, varscan2
- CEBPD | c.69C>T p.P23= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- CFAP221 | c.1608C>T p.F536= | Silent (SNP) | VAF 29/203 reads (14%) | catalogued as rs375418107; called by muse, mutect2, varscan2
- GADL1 | c.621G>A p.S207= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs766955427, COSV56976577; called by muse, mutect2, varscan2
- ITGAE | c.2271C>T p.S757= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as rs551577998, COSV53995670; called by muse, mutect2, varscan2
- ITLN1 | c.642C>T p.G214= | Silent (SNP) | VAF 21/153 reads (14%) | catalogued as rs201111955, COSV58275840; called by muse, mutect2, varscan2
- LTBP3 | c.750C>T p.A250= | Silent (SNP) | VAF 45/219 reads (21%) | catalogued as rs1246484960; called by muse, mutect2, varscan2
- MAPK15 | c.654C>T p.F218= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs782627103; called by muse, mutect2, varscan2
- MRC2 | c.3618C>T p.Y1206= | Silent (SNP) | VAF 82/423 reads (19%) | catalogued as rs746732949, COSV57642421; called by muse, mutect2, varscan2
- PIEZO2 | c.6189C>T p.G2063= | Silent (SNP) | VAF 69/405 reads (17%) | called by muse, mutect2, varscan2
- PLVAP | c.1072C>A p.R358= | Silent (SNP) | VAF 40/254 reads (16%) | catalogued as CM157761; called by muse, mutect2, varscan2
- PPP1R15A | c.1956T>C p.A652= | Silent (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- PRR23C | c.192C>T p.D64= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as rs750832767; called by muse, mutect2, varscan2
- SIPA1L2 | c.3483G>A p.L1161= | Silent (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- VPS13B | c.10089T>A p.T3363= | Silent (SNP) | VAF 55/311 reads (18%) | called by muse, mutect2, varscan2
- VPS35 | c.231G>A p.L77= | Silent (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- ZNF808 | c.1404A>G p.S468= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs761206388; called by muse, mutect2, varscan2
- ABI3BP | c.1576+8162G>A | Intron (SNP) | VAF 8/98 reads (8%) | catalogued as rs553137878, COSV52553228; called by muse, mutect2
- AP2A2 | c.*608C>T | 3'UTR (SNP) | VAF 42/182 reads (23%) | catalogued as rs776573340; called by muse, mutect2, varscan2
- AUP1 | c.340-39A>T | Intron (SNP) | VAF 37/174 reads (21%) | called by muse, mutect2, varscan2
- FAM220BP | n.451C>T | RNA (SNP) | VAF 43/246 reads (17%) | catalogued as rs924653287; called by muse, mutect2, varscan2
- ITGAX | c.*602C>T | 3'UTR (SNP) | VAF 33/259 reads (13%) | catalogued as rs529318380; called by muse, mutect2, varscan2
- LINC02740 | n.285C>T | RNA (SNP) | VAF 27/175 reads (15%) | catalogued as rs1226497149; called by muse, mutect2, varscan2
- MFSD4B | c.*540A>G | 3'UTR (SNP) | VAF 27/133 reads (20%) | catalogued as rs748944052, COSV64349190; called by muse, mutect2, varscan2
